TCGA case TCGA-KM-8639 — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ea84e23-6a0a-4c5d-9c70-d5355a85df35

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,640 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 953 days (2.6 years).
   Pathology details: Consistent pathology review: Yes; Sarcomatoid present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 953 days (2.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 70; ECOG performance status: 2; Timepoint: Other.
- Karnofsky performance status: 100; ECOG performance status: 0.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Calcium: Normal.
- Leukocytes: Normal.
- Platelets: Low.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 20; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1985.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KM-8639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-KM-8639-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-KM-8639-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KM-8639-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KM-8639-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Sarcomatoid features: No; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 5; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 953 days; disease-specific survival: no event (censored), 953 days; disease-free interval: no event (censored), 953 days; progression-free interval: no event (censored), 953 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KM-8639-01A-11D-2389-01): tumor purity 0.62, ploidy 2.1, whole-genome doublings 0.
